CCDI case PBCEIH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/cb3e2c4c-b1d8-4eea-84b3-6179b384b0d3

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 11.7 years (4,280 days).

Biospecimens (3 samples)
- Sample 0DQ7W9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ80N: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ80X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
